TCGA case TCGA-N5-A4RN — Uterine Carcinosarcoma (TCGA-UCS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Corpus uteri; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1d2937e8-6104-4330-b7dc-7bcd79dac927

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 71 years; Vital status: Alive.

Diagnoses (3)
1. Mullerian mixed tumor (the primary disease): ICD-O-3 morphology code: 8950/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Uterus, NOS; Classification of tumor: primary; Age at diagnosis: 71.3 years (26,054 days); Year of diagnosis: 2011; Method of diagnosis: Biopsy; FIGO stage: Stage IVB; FIGO staging edition year: 2009; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Days to last follow up: 1,053 days (2.9 years).
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 28.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 1; Lymph nodes tested: 8.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 0.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 65 days; Days to treatment end: 170 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Radiation Therapy, NOS; Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
2. Intraductal carcinoma, noninfiltrating, NOS: ICD-O-3 morphology code: 8500/2; Tissue or organ of origin: Breast, NOS; Laterality: Right; Classification of tumor: Prior primary; Age at diagnosis: 52.4 years (19,141 days); Days to diagnosis: -6,913 days (-18.9 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -6,903 days (-18.9 years); Treatment anatomic sites: Breast / Lymph Node(s) Axilla.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: -6,837 days (-18.7 years); Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS.
3. Recurrence of diagnosis 1 (Mullerian mixed tumor), site: Pelvis, NOS. Age at diagnosis: 72.9 years (26,624 days); Days to diagnosis: 570 days (1.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Surgery, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 570 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Pelvis, NOS; Days to recurrence: 570 days (1.6 years).
- Days to follow up: 730 days (2.0 years); Disease response: With Tumor.
- Days to follow up: 1,053 days (2.9 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used; Hormonal replacement therapy status: No; Menopause status: Postmenopausal; Number of pregnancies: 2; Pregnancy outcome: Full Term Birth, NOS.
- Timepoint category: Initial Diagnosis; Weight: 76 kg; Height: 152 cm; BMI: 32.9.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-N5-A4RN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 340 mg.
  Slide TCGA-N5-A4RN-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-N5-A4RN-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-N5-A4RN-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History menopausal hormone therapy: No, I have never taken menopausal hormone therapy; Hypertension diagnosis: No; Diabetes diagnosis indicator: No; Pregnancies full term count: 2; History colorectal cancer: No; History neoadjuvant treatment: No; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response.
- Primary pathology: Submitted tumor site: Uterus; Histologic diagnosis: Uterine Carcinosarcoma/MMMT: Homologous Type; Surgical approach at diagnosis: open; Method initial path diagnosis: Office Endometrial Biopsy.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Breast; Other malignancy histological type: Ductal carcinoma in situ.
- Other malignancy form, Surgery: Other malignancy surgery type: Breast conservation surgery and axillary lymph node dissection.
- Other malignancy form, Radiation treatment: History radiation treatment to site of TCGA tumor: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,053 days; disease-specific survival: no event (censored), 1,053 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 570 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-N5-A4RN-01A-12D-A28Q-01): tumor purity 0.93, ploidy 3.33, whole-genome doublings 1.
